Gene-level copy-number profile of tumor specimen C3L-03364-02 from CPTAC case C3L-03364, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 54.3 years (19,844 days).
Specimen C3L-03364-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7764475f-9cfc-4863-a4c0-2fcb87e7299c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03364-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/d5b2699b-258e-4e5c-9ccd-931d595dc45e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 189; copy number 1: 6,242; copy number 2: 46,747; copy number 3: 3,902; copy number 4: 277; copy number 5: 364; copy number 6: 216; copy number 7: 67; copy number 8: 126; copy number 9: 66; copy number 10: 68; copy number 11: 59; copy number 12: 12; copy number 13: 10; copy number 14: 2; copy number 15: 31; copy number 16: 6; copy number 18: 3; copy number 19: 12.

Homozygous deletions (total copy number 0; autosomes only): 189 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:237,122,910–238,555,054, 38 genes: AC107079.1, AC112715.1, COL6A3, AC112721.1, AC112721.2, MLPH, MIR6811, RNU6-1140P, PRLH, RAB17, AC104667.2, AC104667.1, LRRFIP1, AC012076.1, RBM44, RAMP1, SNORD39, UBE2F, UBE2F-SCLY, RNU6-1333P, SCLY, ESPNL, KLHL30, KLHL30-AS1, ERFE, ILKAP, LINC02610, AC012485.1, HES6, PER2, AC012485.3, AC012485.2, TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2, LINC01107.
- chr9:19,507,452–22,455,740, 73 genes (broad region; genes not listed).
- chr9:39,816,542–40,106,661, 1 gene (within-gene range 0–1): FGF7P3.
- chr9:39,886,861–40,153,147, 9 genes: RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:40,992,249–41,654,594, 24 genes (within-gene range 0–1): FRG1HP, PGM5P2, AL353763.2, AL353763.1, BX255923.1, BX255923.2, FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2.
- chr9:64,810,865–64,889,063, 4 genes: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr12:88,142,296–90,112,779, 31 genes: TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1.
- chr15:44,728,988–44,930,622, 9 genes: TRIM69, AC122108.2, SORD2P, AC122108.1, Y_RNA, RNU1-119P, AC090888.3, AC090888.1, RNU6-1108P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,042 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,386,409, 51 genes, copy number 9–18: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3.
- chr5:4,012,708–4,041,764, 2 genes, copy number 8: AC025773.1, AC025187.1.
- chr5:4,436,850–5,490,220, 22 genes, copy number 15: AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1.
- chr5:15,500,180–16,192,709, 8 genes, copy number 10–14: FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6.
- chr5:16,473,038–16,617,058, 1 gene, copy number 13 (within-gene range 12–13): RETREG1.
- chr5:16,617,225–16,623,095, 2 genes, copy number 12: AC022113.1, Y_RNA.
- chr5:29,795,938–32,110,932, 21 genes, copy number 9–16 (within-gene range 2–16): AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5.
- chr5:31,820,564–31,936,159, 8 genes, copy number 10: RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279.
- chr7:130,668,643–131,110,176, 16 genes, copy number 6 (within-gene range 2–6): TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P.
- chr7:131,702,269–132,648,688, 9 genes, copy number 5: AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1, PLXNA4, AC018643.1, AC011625.1.
- chr7:132,753,023–135,977,359, 49 genes, copy number 5: AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P.
- chr7:137,381,037–138,124,595, 12 genes, copy number 6: DGKI, AC090498.1, AC009245.1, CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468.
- chr7:140,241,870–141,702,166, 34 genes, copy number 6: RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P, TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2, AC073878.1, AC073878.2, AGK, AC004918.1, DENND11, AC004918.3.
- chr9:4,490,468–6,066,714, 51 genes, copy number 6: SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1.
- chr9:6,532,467–10,612,723, 31 genes, copy number 5 (within-gene range 3–7): GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1.
- chr11:67,583,742–71,629,421, 126 genes, copy number 5–19 (broad region; genes not listed).
- chr11:71,787,510–72,290,688, 34 genes, copy number 8: FAM86C1P, ALG1L9P, ZNF705E, DEFB108B, RNA5SP342, DEFB130C, AP002495.1, DEFB131B, OR7E128P, OR7E126P, RNF121, AP002490.2, IL18BP, NUMA1, AP002490.1, RNU6-72P, MIR3165, AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1.
- chr11:73,238,975–73,876,901, 21 genes, copy number 6 (within-gene range 3–6): AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4.
- chr11:75,100,563–75,206,549, 1 gene, copy number 5 (within-gene range 3–5): SLCO2B1.
- chr11:75,206,048–79,441,030, 107 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr11:80,321,620–81,556,425, 7 genes, copy number 5–7: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, MTND4LP18, MTND6P25.
- chr11:82,729,940–86,345,943, 64 genes, copy number 5–14 (broad region; genes not listed).
- chr11:86,727,355–87,021,909, 10 genes, copy number 6–11: AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT.
- chr11:89,324,353–90,915,052, 59 genes, copy number 5–8 (within-gene range 4–8): NOX4, H3P34, AP003400.4, AP003400.5, AP003400.1, AP003400.2, AP003400.3, AP003400.6, FOLH1B, UBTFL10, AP003122.6, TRIM77, AP003122.4, AP003122.5, UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2, MIR4490.
- chr11:92,352,096–92,896,470, 1 gene, copy number 5 (within-gene range 4–5): FAT3.
- chr11:92,748,732–94,181,968, 49 genes, copy number 5–12: AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2, DEUP1, SMCO4, SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1, HPRT1P3, HEPHL1, PHBP16, PANX1.
- chr15:25,902,119–26,053,123, 2 genes, copy number 6 (within-gene range 4–6): LINC02346, AC044913.2.
- chr22:40,410,281–40,636,719, 1 gene, copy number 5 (within-gene range 2–5): MRTFA.
- chr22:40,521,800–46,015,498, 175 genes, copy number 5–15 (broad region; genes not listed).
- chr22:49,213,911–49,266,080, 2 genes, copy number 5–7: RPL35P8, Z82202.1.
- chr22:49,738,677–50,801,309, 66 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
